TCGA case TCGA-P5-A733 — Brain Lower Grade Glioma (TCGA-LGG)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Cureline. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/d81b9957-8c82-4006-b111-449fa9fb95ed

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Russia; Age at index: 52 years; Vital status: Alive.

Diagnoses (1)
1. Astrocytoma, NOS: ICD-O-3 morphology code: 9400/3; ICD-10 code: C71.0; Tissue or organ of origin: Cerebrum; Site of resection or biopsy: Nervous system, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 52.4 years (19,142 days); Year of diagnosis: 2013; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 414 days (1.1 years); Sites of involvement: Brain, Frontal lobe.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 21 days; Days to treatment end: 41 days; Treatment dose: 60 Gy; Number of fractions: 30.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Temozolomide; Days to treatment start: 97 days; Days to treatment end: 414 days (1.1 years).

Follow-up (2 entries)
- Days to follow up: 7 days; Disease response: Tumor Free.
- Follow-up contact recording only the day: day 414.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-P5-A733-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT; Initial weight: 300 mg.
  Slide TCGA-P5-A733-01A-01-TSA: Section location: Top; Percent tumor cells: 30; Percent tumor nuclei: 70; Percent normal cells: 10; Percent necrosis: 0; Percent stromal cells: 60; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-P5-A733-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-P5-A733-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Central nervous system; Histologic diagnosis: Astrocytoma; History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: Tumor free; Tumor site: Supratentorial, Frontal Lobe; Treatment outcome first course: Complete Remission/Response.
- Follow-up form: Lost to follow-up: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 414 days; disease-specific survival: no event (censored), 414 days; disease-free interval: no event (censored), 414 days; progression-free interval: no event (censored), 414 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-P5-A733-01A-11D-A32A-01): tumor purity 0.64, ploidy 3.91, whole-genome doublings 1.
